MMRF case MMRF_1055 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6d6eb826-f637-4979-b9b3-73b3f7907238

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 580 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,428 days); ISS stage: II; Days to last known disease status: 580 days (1.6 years); Days to last follow up: 580 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 165 days; Days to treatment end: 165 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 296 days; Days to treatment end: 392 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 414 days (1.1 years); Days to treatment end: 444 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 580.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -15 (ECOG 0): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 52.4 mg/dL; Immunoglobulin G 42.6 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 1.65 g/L; Beta 2 Microglobulin 4.26 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 347 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.73 mmol/L; Albumin 34 g/L; Total Protein 10 g/dL; Glucose 5.34 mmol/L.
- Day 86 (ECOG 1): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.29 mg/dL; Hemoglobin 6.39 mmol/L; Leukocytes 15.5 ×10⁹/L; Absolute Neutrophil 14.5 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.48 mmol/L; Albumin 30 g/L; Total Protein 8.3 g/dL; Glucose 8.42 mmol/L.
- Day 149 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.1 mg/dL; Hemoglobin 6.2 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.6 mmol/L; Albumin 33 g/L; Total Protein 8.7 g/dL; Glucose 6.66 mmol/L.
- Day 244 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 32.3 mg/dL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.53 mmol/L; Albumin 26 g/L; Total Protein 8.5 g/dL; Glucose 7.76 mmol/L.
- Day 350 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.6 mg/dL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.55 mmol/L; Albumin 35 g/L; Total Protein 9 g/dL; Glucose 5.67 mmol/L.
- Day 443 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 50.6 mg/dL; Lactate Dehydrogenase 1.73 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.65 mmol/L; Albumin 32 g/L; Total Protein 8.4 g/dL; Glucose 4.9 mmol/L.
- Day 546 (ECOG 2): M Protein 4.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.908 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 99.9 mg/dL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 3.08 mmol/L; Albumin 32 g/L; Total Protein 12.5 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -15: Weight: 70 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1055_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -15 days.
- Sample MMRF_1055_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -15 days.
